Somatic mutation profile of tumor specimen TCGA-DB-A64L-01A (aliquot TCGA-DB-A64L-01A-11D-A29Q-08) from TCGA case TCGA-DB-A64L, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Oligodendroglioma, NOS; Tissue or organ of origin: Cerebrum; Tumor grade: G2; Age at diagnosis: 67.6 years (24,690 days).
Specimen TCGA-DB-A64L-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 12bb1d2e-1704-4663-ab99-92163065504e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DB-A64L-10A (Blood Derived Normal), aliquot TCGA-DB-A64L-10A-01D-A29Q-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/484a1364-90db-44dd-b692-0b3acb6c9716

The open-access MAF lists 78 somatic variants for this specimen: 63 protein-altering or splice-affecting, 15 silent.
By variant classification: Missense Mutation 57, Silent 15, Splice Site 2, Frame Shift Del 2, Translation Start Site 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 22/68 reads (32%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs121913500, CM1310533, COSV61615239, COSV61615420; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- ABCB10 | c.1511G>A p.R504H | Missense Mutation (SNP) | VAF 54/242 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1006751831, COSV60619855, COSV60624511; called by muse, mutect2, varscan2
- ABLIM1 | c.2060A>G p.D687G | Missense Mutation (SNP) | VAF 11/25 reads (44%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as COSV53300109; called by muse, mutect2, varscan2
- AJUBA | c.29G>A p.R10H | Missense Mutation (SNP) | VAF 8/104 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.669); catalogued as COSV52984474; called by muse, mutect2
- AKAP4 | c.1528C>A p.Q510K | Missense Mutation (SNP) | VAF 8/178 reads (4%) | SIFT tolerated (0.36); PolyPhen probably damaging (0.973); catalogued as COSV62073730; called by muse, mutect2
- B3GNT4 | c.562G>A p.E188K | Missense Mutation (SNP) | VAF 33/96 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.272); catalogued as COSV57335745, COSV99928265; called by muse, mutect2, varscan2
- BSG | c.499A>T p.T167S | Missense Mutation (SNP) | VAF 10/100 reads (10%) | SIFT tolerated (0.67); PolyPhen benign (0.007); catalogued as COSV61076221; called by muse, mutect2
- CA12 | c.392C>T p.S131F | Missense Mutation (SNP) | VAF 21/67 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51604152; called by muse, mutect2, varscan2
- CCNB1IP1 | c.653T>C p.L218S | Missense Mutation (SNP) | VAF 38/84 reads (45%) | SIFT tolerated, low confidence (0.84); PolyPhen benign (0.015); catalogued as COSV62302427; called by muse, mutect2, varscan2
- CD44 | c.85C>T p.R29C | Missense Mutation (SNP) | VAF 20/51 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV53532779; called by muse, mutect2, varscan2
- CHAC1 | c.425C>T p.A142V | Missense Mutation (SNP) | VAF 25/283 reads (9%) | SIFT tolerated (1); PolyPhen benign (0.028); catalogued as rs1196629953, COSV71435923; called by muse, mutect2
- CHD4 | c.2722C>T p.P908S (on ENST00000357008 / NM_001363606.2; = p.P921S on NM_001273.5) | Missense Mutation (SNP) | VAF 9/102 reads (9%) | SIFT tolerated (0.05); PolyPhen benign (0.104); catalogued as COSV58895172, COSV58902370; called by muse, mutect2
- CSH2 | c.467A>T p.D156V | Missense Mutation (SNP) | VAF 20/190 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.814); catalogued as COSV61080032; called by muse, mutect2, varscan2
- DNAH9 | c.4022G>A p.R1341Q | Missense Mutation (SNP) | VAF 13/32 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.23); catalogued as rs774766185, COSV52334821; called by muse, mutect2, varscan2
- EPHA5 | c.1031G>T p.R344M | Missense Mutation (SNP) | VAF 18/176 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); catalogued as COSV56631762, COSV56656573; called by muse, mutect2
- FAM47A | c.236C>T p.P79L | Missense Mutation (SNP) | VAF 45/150 reads (30%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.753); catalogued as COSV60494101; called by muse, mutect2, varscan2
- FERMT3 | c.1367C>T p.S456F (on ENST00000279227 / NM_178443.3; = p.S452F on NM_031471.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as COSV54177072; called by muse, mutect2, varscan2
- FUBP1 | c.416-1G>A p.X139_splice | Splice Site (SNP) | VAF 9/24 reads (38%) | catalogued as COSV53926510, COSV53932495, COSV53933405; called by muse, mutect2, varscan2
- FUBP3 | c.109C>A p.P37T | Missense Mutation (SNP) | VAF 7/89 reads (8%) | SIFT tolerated (0.5); PolyPhen benign (0.077); catalogued as COSV60512875; called by muse, mutect2
- GJB6 | c.250G>A p.V84I | Missense Mutation (SNP) | VAF 8/53 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs538884824, COSV53831864; called by muse, mutect2, varscan2
- GLIS3 | c.1570G>A p.V524M | Missense Mutation (SNP) | VAF 11/80 reads (14%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.539); catalogued as rs201556131, COSV60924191; called by muse, mutect2, varscan2
- GTPBP8 | c.55G>A p.V19M | Missense Mutation (SNP) | VAF 42/82 reads (51%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.006); catalogued as rs565265086, COSV55605831; called by muse, mutect2, varscan2
- HLA-F | c.437C>G p.S146C | Missense Mutation (SNP) | VAF 8/204 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.096); catalogued as COSV52574596, COSV52576699; called by muse, mutect2
- HMCN1 | c.12476C>G p.T4159R | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT tolerated (0.54); PolyPhen benign (0.006); catalogued as COSV54878357; called by muse, mutect2, varscan2
- KIF20B | c.3917T>C p.V1306A (on ENST00000371728 / NM_001284259.2; = p.V1266A on NM_016195.4) | Missense Mutation (SNP) | VAF 3/46 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.185); catalogued as COSV53302427; called by muse, mutect2
- KIF4B | c.2513A>T p.Q838L | Missense Mutation (SNP) | VAF 4/66 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as COSV70527900; called by muse, mutect2
- MBD1 | c.1105C>T p.R369C (on ENST00000269468 / NM_001323950.1; = p.R346C on NM_015845.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 25/215 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV53998236; called by muse, mutect2, varscan2
- MC5R | c.736G>A p.V246M | Missense Mutation (SNP) | VAF 9/180 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.816); catalogued as COSV61253938; called by muse, mutect2
- MRO | c.508T>A p.F170I | Missense Mutation (SNP) | VAF 82/185 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.752); catalogued as rs141296827; called by muse, mutect2, varscan2
- MRPL50 | c.14C>G p.S5C | Missense Mutation (SNP) | VAF 15/118 reads (13%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0); catalogued as rs1253879349, COSV52274352, COSV52275776; called by muse, mutect2, varscan2
- MUC17 | c.4190C>T p.P1397L | Missense Mutation (SNP) | VAF 50/576 reads (9%) | SIFT tolerated (0.05); PolyPhen benign (0.067); catalogued as rs141608296, COSV60280453; called by muse, mutect2
- MYH4 | c.361C>A p.L121I | Missense Mutation (SNP) | VAF 17/172 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.734); catalogued as COSV55112545; called by muse, mutect2
- NCOR2 | c.5422C>T p.R1808W | Missense Mutation (SNP) | VAF 25/70 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs375229118; called by muse, mutect2, varscan2
- NELL1 | c.521T>C p.V174A | Missense Mutation (SNP) | VAF 21/54 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.891); catalogued as COSV54239922; called by muse, mutect2, varscan2
- NHS | c.436G>A p.A146T | Missense Mutation (SNP) | VAF 11/25 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.673); catalogued as COSV66271423; called by muse, mutect2, varscan2
- NLRP1 | c.2971G>A p.V991M | Missense Mutation (SNP) | VAF 14/344 reads (4%) | SIFT tolerated (0.2); PolyPhen benign (0.014); catalogued as COSV52558776; called by muse, mutect2
- NLRP5 | c.196C>A p.Q66K | Missense Mutation (SNP) | VAF 10/72 reads (14%) | SIFT tolerated (0.23); PolyPhen benign (0.339); catalogued as COSV66762151; called by muse, mutect2, varscan2
- NOTCH1 | c.2806G>T p.G936C | Missense Mutation (SNP) | VAF 77/185 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53029406, COSV53084597; called by muse, mutect2, varscan2
- PCDHGA1 | c.469G>T p.G157W | Missense Mutation (SNP) | VAF 23/165 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.965); catalogued as rs748688708, COSV65294993; called by muse, mutect2, varscan2
- PITPNM1 | c.1375G>A p.A459T | Missense Mutation (SNP) | VAF 60/154 reads (39%) | SIFT tolerated (0.55); PolyPhen benign (0.022); catalogued as rs151117956; called by muse, mutect2, varscan2
- PLD1 | c.73A>T p.I25L | Missense Mutation (SNP) | VAF 24/94 reads (26%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.03); catalogued as rs1373674701, COSV60565439; called by muse, mutect2, varscan2
- PNMA3 | c.896G>T p.S299I | Missense Mutation (SNP) | VAF 13/92 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.347); catalogued as COSV64721804; called by muse, mutect2, varscan2
- PROKR1 | c.281G>A p.R94H | Missense Mutation (SNP) | VAF 18/246 reads (7%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs371409546, COSV58136615; called by muse, mutect2
- PRPF8 | c.3041A>G p.N1014S | Missense Mutation (SNP) | VAF 19/60 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV59260712; called by muse, mutect2, varscan2
- RABL3 | c.412A>T p.N138Y | Missense Mutation (SNP) | VAF 80/251 reads (32%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.93); catalogued as COSV56335048, COSV56336442; called by muse, mutect2, varscan2
- REPS2 | c.871C>T p.R291* | Nonsense Mutation (SNP) | VAF 77/228 reads (34%) | catalogued as COSV58178962; called by muse, mutect2, varscan2
- RNASE8 | c.372C>G p.H124Q | Missense Mutation (SNP) | VAF 27/209 reads (13%) | SIFT tolerated (0.61); PolyPhen benign (0.014); catalogued as COSV57551378; called by muse, mutect2, varscan2
- RPA1 | c.1746+1G>A p.X582_splice | Splice Site (SNP) | VAF 44/111 reads (40%) | catalogued as rs745884794, COSV54607117; called by muse, mutect2, varscan2
- RTN3 | c.1969G>A p.A657T (on ENST00000377819 / NM_001265589.2; = p.A638T on NM_201428.3) | Missense Mutation (SNP) | VAF 5/84 reads (6%) | SIFT tolerated (0.21); PolyPhen benign (0.091); catalogued as COSV58027047; called by muse, mutect2
- SEMA6D | c.2621A>G p.D874G (on ENST00000316364 / NM_153618.2; = p.D812G on NM_020858.2) | Missense Mutation (SNP) | VAF 10/141 reads (7%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.995); catalogued as COSV60372961; called by muse, mutect2
- SP3 | c.2000A>G p.E667G | Missense Mutation (SNP) | VAF 13/61 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59466207; called by muse, mutect2, varscan2
- TAF1L | c.3755G>A p.R1252Q | Missense Mutation (SNP) | VAF 15/92 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs374131496; called by muse, mutect2, varscan2
- THEMIS2 | c.976C>T p.R326W | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs773899832, COSV61077256; called by muse, mutect2, varscan2
- TMC1 | c.2129T>C p.V710A | Missense Mutation (SNP) | VAF 39/300 reads (13%) | SIFT tolerated (0.11); PolyPhen benign (0.042); catalogued as COSV52767784; called by muse, mutect2, varscan2
- TRMT5 | c.314T>G p.I105R | Missense Mutation (SNP) | VAF 19/160 reads (12%) | SIFT tolerated (0.31); PolyPhen benign (0.001); catalogued as COSV50781082; called by muse, mutect2, varscan2
- TRPM1 | c.3542G>A p.R1181H | Missense Mutation (SNP) | VAF 8/77 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.767); catalogued as rs766982197, COSV56630705; called by muse, mutect2
- UQCR11 | c.1A>G p.M1? | Translation Start Site (SNP) | VAF 5/20 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.197); catalogued as rs1487630794, COSV53645689; called by muse, mutect2
- USP9X | c.5440G>A p.D1814N | Missense Mutation (SNP) | VAF 17/113 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV61066202; called by muse, mutect2, varscan2
- VSTM2L | c.178A>G p.M60V | Missense Mutation (SNP) | VAF 45/276 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.14); catalogued as rs778180937, COSV65095553; called by muse, mutect2, varscan2
- ZBTB45 | c.670G>A p.E224K | Missense Mutation (SNP) | VAF 58/423 reads (14%) | SIFT tolerated (0.44); PolyPhen benign (0.015); catalogued as rs780277513, COSV54018044; called by muse, mutect2, varscan2
- ZNF263 | c.1259G>A p.R420H | Missense Mutation (SNP) | VAF 56/149 reads (38%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs149007034; called by muse, mutect2, varscan2
- CIC | c.1110_1113del p.S370Rfs*6 | Frame Shift Del (DEL) | VAF 69/125 reads (55%) | called by mutect2, pindel, varscan2
- OR10J1 | c.6_7del p.N5Lfs*6 | Frame Shift Del (DEL) | VAF 11/92 reads (12%) | called by mutect2, varscan2
- ADRA2B | c.474G>A p.P158= | Silent (SNP) | VAF 10/64 reads (16%) | catalogued as COSV69787197; called by muse, mutect2, varscan2
- CD93 | c.1731C>T p.D577= | Silent (SNP) | VAF 46/152 reads (30%) | catalogued as rs750953262, COSV55663341; called by muse, mutect2, varscan2
- CES2 | c.696G>A p.T232= | Silent (SNP) | VAF 58/141 reads (41%) | catalogued as rs1325829385, COSV57696207; called by muse, mutect2, varscan2
- FCRLA | c.435C>T p.P145= (on ENST00000367959; = p.P122= on NM_032738.4) | Silent (SNP) | VAF 34/112 reads (30%) | catalogued as rs376754195; called by muse, mutect2, varscan2
- GCNT2 | c.36G>A p.A12= | Silent (SNP) | VAF 14/121 reads (12%) | catalogued as rs142352495; called by muse, mutect2
- HOXA11 | c.174C>T p.R58= | Silent (SNP) | VAF 21/166 reads (13%) | catalogued as COSV50052830; called by muse, mutect2, varscan2
- INTS4 | c.609C>T p.Y203= | Silent (SNP) | VAF 70/211 reads (33%) | catalogued as rs762644302, COSV71087173; called by muse, mutect2, varscan2
- IRF8 | c.906C>T p.N302= | Silent (SNP) | VAF 8/54 reads (15%) | catalogued as rs770342843, COSV51896689; called by muse, mutect2, varscan2
- KCNB2 | c.249C>T p.N83= | Silent (SNP) | VAF 34/102 reads (33%) | catalogued as COSV101578951, COSV73048960; called by muse, mutect2, varscan2
- METTL3 | c.135C>T p.T45= | Silent (SNP) | VAF 13/116 reads (11%) | catalogued as COSV52967572; called by muse, mutect2, varscan2
- OSMR | c.1797C>T p.F599= | Silent (SNP) | VAF 24/68 reads (35%) | catalogued as COSV57081181; called by muse, mutect2, varscan2
- PTCH2 | c.3087C>T p.G1029= | Silent (SNP) | VAF 21/42 reads (50%) | catalogued as rs753377256, COSV64709757; called by muse, mutect2, varscan2
- SLC5A7 | c.102C>T p.S34= | Silent (SNP) | VAF 31/108 reads (29%) | catalogued as rs778941657, COSV50888948; called by muse, mutect2, varscan2
- TINAG | c.108T>C p.T36= | Silent (SNP) | VAF 15/125 reads (12%) | catalogued as COSV52505703; called by muse, mutect2, varscan2
- TRIM71 | c.1974C>T p.G658= | Silent (SNP) | VAF 27/94 reads (29%) | catalogued as rs748729591, COSV67470161; called by muse, mutect2, varscan2
